Somatic mutation profile of tumor specimen TCGA-GV-A3JZ-01A (aliquot TCGA-GV-A3JZ-01A-11D-A21A-08) from TCGA case TCGA-GV-A3JZ, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 55.9 years (20,420 days).
Specimen TCGA-GV-A3JZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb2850b4-519d-48c1-8351-823120fd1165.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GV-A3JZ-10A (Blood Derived Normal), aliquot TCGA-GV-A3JZ-10A-01D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ecd0dee-08b8-4f4b-a3a7-fff896747aa4

The open-access MAF lists 507 somatic variants for this specimen: 381 protein-altering or splice-affecting, 114 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 337, Silent 114, Nonsense Mutation 32, Splice Site 8, RNA 6, Intron 6, Splice Region 2, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IQCB1 | c.1036G>T p.E346* | Nonsense Mutation (SNP) | VAF 38/162 reads (23%) | catalogued as rs387907009, CM110329, COSV60438872; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 103/113 reads (91%) | hotspot (GDC flag); catalogued as rs866380588, COSV52660737, COSV52978302; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC2 | c.1733A>C p.K578T | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.913); catalogued as COSV64988530; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.877G>C p.E293Q | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.026); catalogued as rs201048015, COSV56473031; called by muse, mutect2, varscan2
- AC100868.1 | c.1505G>T p.R502I | Missense Mutation (SNP) | VAF 49/379 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51849894; called by muse, mutect2, varscan2
- ADAMTS16 | c.2476G>A p.E826K | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs552210881, COSV57007046; called by muse, mutect2
- ADGRB3 | c.2939G>A p.R980K | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV53260222; called by muse, mutect2, varscan2
- ADIPOR1 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV61852473; called by muse, mutect2, varscan2
- AHNAK | c.8665G>C p.D2889H | Missense Mutation (SNP) | VAF 86/389 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV57210571; called by muse, mutect2, varscan2
- AHNAK | c.8038G>C p.D2680H | Missense Mutation (SNP) | VAF 56/222 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57224530; called by muse, varscan2
- AHNAK | c.6579G>C p.L2193F | Missense Mutation (SNP) | VAF 130/541 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV57230143; called by muse, mutect2, varscan2
- AMBRA1 | c.2279C>G p.S760C (on ENST00000458649 / NM_001367468.1; = p.S670C on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.62); catalogued as COSV54062533; called by muse, mutect2, varscan2
- AMER3 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 74/139 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58470053; called by muse, mutect2, varscan2
- ANKRD50 | c.3053C>T p.S1018F | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV72386314; called by muse, mutect2, varscan2
- ANKS4B | c.1168G>T p.G390C | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61140292; called by muse, mutect2
- AP000721.1 | c.83C>G p.S28W | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV58479021; called by muse, mutect2, varscan2
- ARHGAP26 | c.1432+1G>T p.X478_splice | Splice Site (SNP) | VAF 39/102 reads (38%) | catalogued as COSV50841242; called by muse, mutect2, varscan2
- ARHGAP5 | c.959C>G p.S320* | Nonsense Mutation (SNP) | VAF 18/42 reads (43%) | catalogued as COSV61535496; called by muse, mutect2, varscan2
- ARID4B | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.257); catalogued as COSV51602597, COSV51611202; called by muse, mutect2
- ARMCX5 | c.792G>C p.L264F | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.946); catalogued as COSV55767641; called by muse, mutect2, varscan2
- ARSI | c.1627C>T p.R543C | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.142); catalogued as rs142267983; called by muse, mutect2, varscan2
- ASXL2 | c.676C>T p.Q226* | Nonsense Mutation (SNP) | VAF 97/110 reads (88%) | catalogued as COSV55463524; called by muse, mutect2, varscan2
- ATF6 | c.985G>C p.E329Q | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63406811; called by muse, mutect2
- ATP12A | c.1781C>T p.P594L | Missense Mutation (SNP) | VAF 69/101 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752142201, COSV54520393; called by muse, mutect2, varscan2
- ATP13A2 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 164/251 reads (65%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as rs770576740, COSV58703696; called by muse, mutect2, varscan2
- BACH2 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 67/117 reads (57%) | SIFT tolerated (0.66); PolyPhen benign (0.037); catalogued as COSV57589297; called by muse, mutect2, varscan2
- BARD1 | c.605C>G p.S202C | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs1018602332, COSV53617406; called by muse, mutect2, varscan2
- BBS9 | c.2617G>A p.E873K (on ENST00000242067 / NM_001348036.1; = p.E833K on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.107); catalogued as COSV54187262; called by muse, mutect2, varscan2
- BCAT1 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373461769; called by muse, mutect2, varscan2
- BCDIN3D | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs772541621, COSV61702417; called by muse, mutect2, varscan2
- BCOR | c.3124G>A p.E1042K | Missense Mutation (SNP) | VAF 30/32 reads (94%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as rs1178525455, COSV60718432; called by muse, mutect2, varscan2
- BLVRA | c.245A>G p.D82G | Missense Mutation (SNP) | VAF 120/187 reads (64%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV55516336; called by muse, mutect2, varscan2
- BOLA3 | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.898); catalogued as COSV54877526, COSV99768102; called by muse, mutect2, varscan2
- BRCA2 | c.3376G>C p.E1126Q | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66458745, COSV66462210; called by muse, mutect2, varscan2
- BRCA2 | c.4156G>T p.D1386Y | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555283600, COSV101204007, COSV66462217; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.4709G>C p.R1570T | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV66462225; called by muse, mutect2, varscan2
- BRCA2 | c.5683G>A p.E1895K | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs146351301, CM057867, COSV66462233; ClinVar: uncertain significance / likely benign; called by muse, varscan2
- BRCA2 | c.5731G>A p.D1911N | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.037); catalogued as COSV66460775; called by muse, varscan2
- BSN | c.8827G>A p.E2943K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs866956428, COSV56527517; called by muse, mutect2, varscan2
- BTN1A1 | c.580C>G p.P194A | Missense Mutation (SNP) | VAF 100/107 reads (93%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV55069607; called by muse, mutect2, varscan2
- BTN3A1 | c.666C>G p.I222M | Missense Mutation (SNP) | VAF 269/287 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV50025388; called by muse, mutect2, varscan2
- CABLES2 | c.857C>T p.S286L | Missense Mutation (SNP) | VAF 56/238 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs1038431977, COSV54158438; called by muse, mutect2, varscan2
- CAMTA2 | c.2090G>A p.W697* | Nonsense Mutation (SNP) | VAF 20/142 reads (14%) | catalogued as COSV61837619; called by muse, mutect2, varscan2
- CAND1 | c.2674C>G p.L892V | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV73389783; called by muse, mutect2, varscan2
- CARS2 | c.479C>T p.T160M | Missense Mutation (SNP) | VAF 48/184 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as rs143602497; called by muse, mutect2, varscan2
- CBFA2T2 | c.594G>C p.Q198H | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1221246046, COSV60075886; called by muse, mutect2, varscan2
- CCDC185 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 57/78 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as rs143800669, COSV64821014; called by muse, mutect2, varscan2
- CCDC73 | c.395C>G p.S132C | Missense Mutation (SNP) | VAF 36/45 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV58804795; called by muse, mutect2, varscan2
- CCDC80 | c.614G>A p.S205N | Missense Mutation (SNP) | VAF 72/143 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs1216753978, COSV52819921; called by muse, mutect2, varscan2
- CCT3 | c.1571C>T p.S524L | Missense Mutation (SNP) | VAF 40/242 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.464); catalogued as COSV55291466; called by muse, mutect2, varscan2
- CDH4 | c.2458G>C p.D820H | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64648564, COSV64674509; called by muse, mutect2, varscan2
- CDH5 | c.637A>C p.K213Q | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.021); catalogued as COSV58519947; called by muse, varscan2
- CDH5 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 80/192 reads (42%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.446); catalogued as COSV58519951; called by muse, mutect2, varscan2
- CEACAM19 | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.203); catalogued as COSV62552303; called by muse, mutect2, varscan2
- CEP192 | c.6173C>T p.S2058L | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV58066744; called by muse, mutect2, varscan2
- CFAP61 | c.1762T>G p.Y588D | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55647301; called by muse, mutect2, varscan2
- CFAP61 | c.2681G>C p.G894A | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.346); catalogued as COSV55620855, COSV55647312, COSV99072304; called by muse, mutect2, varscan2
- CFL2 | c.184G>C p.D62H | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV53312792; called by muse, mutect2, varscan2
- CHD1 | c.683A>G p.D228G | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV52344754; called by muse, mutect2, varscan2
- CHD6 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.64); PolyPhen benign (0.199); catalogued as rs745874049, COSV100498683, COSV58562396; called by muse, varscan2
- CHERP | c.106G>C p.E36Q | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.231); catalogued as COSV52227721; called by muse, mutect2, varscan2
- CHRD | c.641C>G p.S214* | Nonsense Mutation (SNP) | VAF 28/93 reads (30%) | catalogued as COSV52611594; called by muse, mutect2, varscan2
- CIBAR1 | c.859T>C p.F287L | Missense Mutation (SNP) | VAF 31/42 reads (74%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV63898293; called by muse, mutect2, varscan2
- CIPC | c.920C>T p.S307L | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV62377419; called by muse, mutect2, varscan2
- CLTCL1 | c.3298G>C p.E1100Q | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV54233688, COSV54239260; called by muse, mutect2
- CNN2 | c.801G>C p.Q267H | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV54037314; called by muse, mutect2, varscan2
- COL5A2 | c.1478C>T p.P493L | Missense Mutation (SNP) | VAF 57/209 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.041); catalogued as rs755909523, COSV66415211; called by muse, mutect2, varscan2
- COL6A2 | c.1120del p.X374_splice | Splice Site (DEL) | VAF 17/40 reads (43%) | catalogued as COSV100154027; called by mutect2, pindel, varscan2
- COPA | c.2262G>C p.Q754H | Missense Mutation (SNP) | VAF 50/470 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.042); catalogued as COSV54109498; called by muse, mutect2, varscan2
- COX15 | c.808C>G p.L270V | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV50013195; called by muse, mutect2, varscan2
- COX6A1 | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 26/34 reads (76%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV57569438, COSV57569488, COSV57569746; called by muse, mutect2, varscan2
- CSK | c.520G>C p.E174Q | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.013); catalogued as COSV54976032; called by muse, mutect2, varscan2
- CSTF2 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.952); catalogued as COSV65895172; called by muse, mutect2, varscan2
- CTH | c.731G>T p.G244V | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100697086, COSV61009801; called by muse, mutect2, varscan2
- CTIF | c.1291G>A p.A431T | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs1401421812, COSV56491696; called by muse, mutect2, varscan2
- CTTN | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 49/220 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57233155, COSV57236218; called by muse, mutect2, varscan2
- CYB5R3 | c.106C>T p.L36F | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV61546623; called by muse, mutect2, varscan2
- CYP39A1 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 181/322 reads (56%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV51499262; called by muse, mutect2, varscan2
- DAPK1 | c.1968G>C p.E656D | Missense Mutation (SNP) | VAF 77/346 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.159); catalogued as COSV63791966; called by muse, mutect2, varscan2
- DDC | c.1134C>G p.I378M | Missense Mutation (SNP) | VAF 31/190 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV63567771; called by muse, mutect2, varscan2
- DDX21 | c.1555G>C p.E519Q | Missense Mutation (SNP) | VAF 42/71 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV62556836; called by muse, mutect2, varscan2
- DDX47 | c.1139A>T p.H380L | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.045); catalogued as COSV61912098; called by muse, mutect2, varscan2
- DENND11 | c.1101G>T p.Q367H | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.132); catalogued as rs774297867, COSV72097820; called by mutect2, varscan2
- DFFA | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65478259; called by muse, mutect2, varscan2
- DIAPH1 | c.2245C>T p.P749S | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.966); catalogued as COSV53888721; called by muse, mutect2, varscan2
- DIP2B | c.3235C>G p.P1079A | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56591962; called by muse, varscan2
- DIP2B | c.3466C>G p.L1156V | Missense Mutation (SNP) | VAF 55/193 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56591995; called by muse, mutect2, varscan2
- DRC7 | c.93G>A p.M31I | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.006); catalogued as COSV61053300; called by muse, mutect2, varscan2
- DSE | c.2296A>C p.N766H | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV59067338; called by muse, mutect2, varscan2
- DST | c.1759C>A p.P587T (on ENST00000361203 / NM_001374722.1; = p.P261T on NM_001723.6) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55039682; called by muse, mutect2
- DYNC2I1 | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs748585110; called by muse, mutect2, varscan2
- DYSF | c.1508C>T p.S503L | Missense Mutation (SNP) | VAF 43/49 reads (88%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs144931729, COSV50314943; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DZIP1 | c.2251G>A p.E751K (on ENST00000347108; = p.E732K on NM_014934.5) | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.908); catalogued as COSV61270150; called by muse, mutect2, varscan2
- EEF1G | c.1062G>C p.K354N | Missense Mutation (SNP) | VAF 46/68 reads (68%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as COSV61323398; called by muse, mutect2, varscan2
- EFCAB3 | c.1135A>G p.T379A | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as rs780684183, COSV100540066; called by muse, mutect2, varscan2
- ELN | c.1459C>T p.P487S | Missense Mutation (SNP) | VAF 162/399 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as COSV52708036; called by muse, mutect2, varscan2
- ELP1 | c.2527C>A p.H843N | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV65899943; called by muse, mutect2, varscan2
- ENO2 | c.1179C>G p.I393M | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV57545770; called by muse, mutect2, varscan2
- ENTPD6 | c.1100G>C p.R367T | Missense Mutation (SNP) | VAF 126/204 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.245); catalogued as COSV61751281, COSV61752448; called by muse, mutect2, varscan2
- EP300 | c.1891C>G p.H631D | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99609912; called by muse, mutect2, varscan2
- EP400 | c.8284G>A p.G2762S | Missense Mutation (SNP) | VAF 62/120 reads (52%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.769); catalogued as rs748082192, COSV57786310; called by muse, mutect2, varscan2
- EPPK1 | c.3487G>C p.E1163Q | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.11); catalogued as rs782783704, COSV73262375; called by muse, mutect2, varscan2
- EPS15 | c.649A>T p.T217S | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.86); PolyPhen benign (0.1); catalogued as COSV65545336; called by muse, mutect2, varscan2
- ERICH3 | c.4325C>G p.S1442* | Nonsense Mutation (SNP) | VAF 66/255 reads (26%) | catalogued as rs1468572689; called by muse, mutect2, varscan2
- FAM171A1 | c.98-1G>C p.X33_splice | Splice Site (SNP) | VAF 15/90 reads (17%) | catalogued as COSV65320107; called by muse, mutect2, varscan2
- FAM20A | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 47/249 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56838326; called by muse, mutect2, varscan2
- FAM3D | c.146-1G>C p.X49_splice | Splice Site (SNP) | VAF 73/120 reads (61%) | catalogued as COSV62559575; called by muse, mutect2, varscan2
- FAM83F | c.1373G>A p.S458N | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.005); catalogued as COSV61001549; called by muse, mutect2, varscan2
- FDXR | c.899C>T p.S300F (on ENST00000293195 / NM_024417.5; = p.S306F on NM_004110.6) | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.525); catalogued as COSV53117868; called by muse, mutect2, varscan2
- FEZF1 | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 45/209 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV58659687; called by muse, mutect2, varscan2
- FGD2 | c.883-1G>A p.X295_splice | Splice Site (SNP) | VAF 31/420 reads (7%) | catalogued as COSV51466129; called by muse, mutect2
- FGL2 | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758029651, COSV50385575; called by muse, mutect2, varscan2
- FH | c.1357C>G p.L453V | Missense Mutation (SNP) | VAF 162/250 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1218102979, COSV63818494; called by muse, mutect2, varscan2
- FLG | c.7799G>A p.R2600K | Missense Mutation (SNP) | VAF 32/320 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.035); catalogued as COSV100912246, COSV64245155; called by muse, mutect2, varscan2
- FMO2 | c.1018G>T p.D340Y | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV52950402; called by muse, mutect2, varscan2
- FMO4 | c.295G>C p.D99H | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.438); catalogued as rs1244787278, COSV63000749; called by muse, mutect2, varscan2
- FMO4 | c.352G>C p.D118H | Missense Mutation (SNP) | VAF 130/397 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV63001945; called by muse, varscan2
- FMO4 | c.421G>C p.D141H | Missense Mutation (SNP) | VAF 313/868 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100882036, COSV63001947; called by muse, varscan2
- FOCAD | c.3628G>A p.E1210K | Missense Mutation (SNP) | VAF 114/118 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58107664; called by muse, mutect2, varscan2
- FOXE1 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.179); catalogued as rs764965228, COSV64301037; called by muse, mutect2, varscan2
- FOXRED2 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 73/122 reads (60%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as rs1395987549, COSV53399548, COSV53401578; called by muse, mutect2, varscan2
- FRAS1 | c.10324G>A p.D3442N | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV53647585; called by muse, mutect2, varscan2
- GAK | c.3544G>C p.D1182H | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV58509622; called by muse, mutect2, varscan2
- GALNT1 | c.163C>T p.H55Y | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV52455150; called by muse, mutect2, varscan2
- GARNL3 | c.2759G>T p.G920V | Missense Mutation (SNP) | VAF 98/180 reads (54%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs777781747, COSV59230488; called by muse, mutect2, varscan2
- GJA10 | c.1096C>G p.Q366E | Missense Mutation (SNP) | VAF 110/190 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.112); catalogued as COSV65356251; called by muse, mutect2, varscan2
- GNE | c.414G>C p.M138I (on ENST00000396594 / NM_001128227.3; = p.M107I on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV64953085; called by muse, mutect2, varscan2
- GNE | c.97G>A p.E33K (on ENST00000396594 / NM_001128227.3; = p.E2K on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV64953107; called by muse, mutect2, varscan2
- GPR101 | c.856G>T p.A286S | Missense Mutation (SNP) | VAF 95/180 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV53239339, COSV53240415; called by muse, mutect2, varscan2
- GRB10 | c.481C>G p.P161A | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as COSV60016611; called by muse, mutect2, varscan2
- GRIK1 | c.2272G>C p.E758Q | Missense Mutation (SNP) | VAF 52/89 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV58731940; called by muse, mutect2, varscan2
- GRIK1 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as COSV58714723; called by muse, mutect2, varscan2
- GSDMA | c.866T>G p.L289R | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56977106; called by muse, mutect2
- GSDMC | c.209C>G p.S70C | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as COSV52699322; called by muse, mutect2, varscan2
- GSG1 | c.190G>A p.E64K (on ENST00000651961 / NM_001080555.4; = p.E51K on NM_031289.5) | Missense Mutation (SNP) | VAF 65/171 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs771340638, COSV60973534; called by muse, mutect2, varscan2
- H2AZ2 | c.184C>T p.L62F | Missense Mutation (SNP) | VAF 101/149 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV56063116; called by muse, mutect2, varscan2
- H2BW1 | c.489C>G p.L163= | Splice Region (SNP) | VAF 39/48 reads (81%) | catalogued as COSV54221452; called by muse, mutect2, varscan2
- H4C9 | c.153C>G p.I51M | Missense Mutation (SNP) | VAF 234/418 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs753701748, COSV62889851; called by muse, mutect2, varscan2
- HBS1L | c.767G>A p.G256E | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.115); catalogued as COSV63202844; called by muse, mutect2, varscan2
- HKDC1 | c.403G>T p.A135S | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.91); PolyPhen benign (0.005); catalogued as rs1299715766, COSV63575565, COSV63579328; called by muse, mutect2, varscan2
- HOXC9 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 41/66 reads (62%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV57717406; called by muse, mutect2, varscan2
- HOXD13 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 79/92 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV66832977; called by muse, mutect2, varscan2
- HRNR | c.959C>G p.S320C | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV64262891, COSV64262902; called by muse, mutect2, varscan2
- HRNR | c.566C>A p.S189Y | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV64262908; called by muse, mutect2, varscan2
- HSF1 | c.749C>G p.S250C | Missense Mutation (SNP) | VAF 50/241 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.894); catalogued as COSV60049329; called by muse, mutect2, varscan2
- ICE1 | c.1355C>T p.S452F | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV56821761, COSV56832454; called by muse, mutect2, varscan2
- ICOS | c.242A>T p.K81I | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.035); catalogued as COSV57031094; called by muse, mutect2
- ICOS | c.244T>C p.F82L | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV57031102; called by muse, mutect2
- IDH3B | c.1119C>G p.I373M | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV61390187; called by muse, mutect2, varscan2
- IDH3B | c.838C>G p.L280V | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.498); catalogued as COSV100249917, COSV61391712; called by muse, mutect2, varscan2
- IFI16 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as COSV55540115; called by muse, mutect2, varscan2
- IFNA4 | c.533C>T p.S178L | Missense Mutation (SNP) | VAF 421/489 reads (86%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as rs746359287, COSV70180385; called by muse, mutect2, varscan2
- IL17RA | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60056263; called by muse, mutect2, varscan2
- IMP3 | c.97G>A p.V33M | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as COSV100145929, COSV59189675; called by muse, mutect2, varscan2
- INKA1 | c.797C>A p.A266E | Missense Mutation (SNP) | VAF 86/356 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV60968812; called by muse, mutect2, varscan2
- INO80 | c.2698G>C p.E900Q | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.979); catalogued as rs750579112, COSV62742735; called by muse, mutect2, varscan2
- ITGB1BP2 | c.7C>G p.L3V | Missense Mutation (SNP) | VAF 56/58 reads (97%) | SIFT tolerated (0.16); PolyPhen benign (0.303); catalogued as COSV52140278; called by muse, mutect2, varscan2
- ITIH6 | c.2981C>A p.P994H | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV54494543; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.937G>C p.D313H | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59828423; called by muse, mutect2, varscan2
- KCNQ5 | c.2057G>A p.R686K | Missense Mutation (SNP) | VAF 83/172 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.197); catalogued as COSV59682677; called by muse, mutect2, varscan2
- KCNT1 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.586); catalogued as COSV53710664; called by muse, varscan2
- KHDC4 | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs753953258, COSV64165054, COSV64165725; called by muse, mutect2, varscan2
- KLHL10 | c.1465G>C p.D489H | Missense Mutation (SNP) | VAF 103/236 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV53173002; called by muse, mutect2, varscan2
- KLHL31 | c.1719G>A p.W573* | Nonsense Mutation (SNP) | VAF 16/63 reads (25%) | catalogued as COSV99057224; called by muse, mutect2, varscan2
- KNDC1 | c.5186C>G p.S1729C | Missense Mutation (SNP) | VAF 45/57 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV58846141; called by muse, mutect2, varscan2
- KRT18 | c.737C>A p.A246D | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV66316641; called by muse, mutect2, varscan2
- L2HGDH | c.823G>C p.D275H | Missense Mutation (SNP) | VAF 65/152 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.537); catalogued as COSV55560706; called by muse, mutect2, varscan2
- LAMA2 | c.3252A>T p.K1084N | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as COSV70355007; called by muse, mutect2, varscan2
- LAMA4 | c.3880G>A p.D1294N (on ENST00000230538 / NM_001105206.3; = p.D1287N on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57904796, COSV57905564; called by muse, varscan2
- LAMA5 | c.1072+2T>G p.X358_splice | Splice Site (SNP) | VAF 39/103 reads (38%) | catalogued as COSV53372404; called by muse, mutect2, varscan2
- LIPC | c.634G>C p.D212H | Missense Mutation (SNP) | VAF 229/383 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54427196; called by muse, mutect2, varscan2
- LMX1B | c.376G>T p.E126* | Nonsense Mutation (SNP) | VAF 21/59 reads (36%) | catalogued as COSV100827293; called by muse, varscan2
- LMX1B | c.746G>C p.R249P | Missense Mutation (SNP) | VAF 60/110 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as CM153363, CM981220, COSV100827193, COSV62741896; called by muse, mutect2, varscan2
- LONP2 | c.324C>G p.F108L | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as rs769086778, COSV53526185; called by muse, mutect2, varscan2
- LRRC8E | c.1114C>T p.Q372* | Nonsense Mutation (SNP) | VAF 20/77 reads (26%) | catalogued as COSV60718584; called by muse, mutect2, varscan2
- MACF1 | c.3529G>C p.E1177Q | Missense Mutation (SNP) | VAF 95/151 reads (63%) | catalogued as COSV58402059; called by muse, mutect2, varscan2
- MAGI3 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as COSV56844089; called by muse, mutect2, varscan2
- MECOM | c.790G>T p.D264Y (on ENST00000468789 / NM_001105078.4; = p.D452Y on NM_004991.4) | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV52974813; called by muse, mutect2, varscan2
- MESD | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV55726496; called by muse, mutect2, varscan2
- METTL7A | c.469C>T p.L157F | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1332876486, COSV100153691, COSV59840714; called by muse, mutect2, varscan2
- MFF | c.455G>C p.R152T | Missense Mutation (SNP) | VAF 40/64 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58826781; called by muse, mutect2, varscan2
- MIS18BP1 | c.2521G>A p.E841K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV60371215, COSV60373092; called by muse, mutect2
- MMEL1 | c.1595C>T p.S532L | Missense Mutation (SNP) | VAF 54/101 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.266); catalogued as COSV56526185; called by muse, mutect2, varscan2
- MOGS | c.1117G>C p.E373Q | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as COSV51971698; called by muse, varscan2
- MOGS | c.1052G>C p.R351T | Missense Mutation (SNP) | VAF 80/190 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.076); catalogued as rs368536824; ClinVar: uncertain significance; called by muse, varscan2
- MPP6 | c.239T>G p.L80W | Missense Mutation (SNP) | VAF 15/161 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56042862; called by muse, mutect2
- MUC5B | c.14569G>A p.V4857M | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs540362271, COSV71590390; called by muse, mutect2, varscan2
- MYH9 | c.5293G>A p.D1765N | Missense Mutation (SNP) | VAF 43/189 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as rs779971012, COSV53393135; called by muse, mutect2, varscan2
- MYOM3 | c.3940G>A p.E1314K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV58400990; called by muse, mutect2, varscan2
- NALCN | c.3739G>C p.V1247L | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.028); catalogued as COSV51964915; called by muse, mutect2, varscan2
- NCOA2 | c.4145G>A p.S1382N | Missense Mutation (SNP) | VAF 48/75 reads (64%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV51223191; called by muse, mutect2, varscan2
- NEFM | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55334950; called by muse, mutect2, varscan2
- NFE2 | c.338C>G p.S113* | Nonsense Mutation (SNP) | VAF 51/175 reads (29%) | catalogued as COSV56455235, COSV56455351; called by muse, mutect2, varscan2
- NINL | c.1963G>A p.E655K | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); catalogued as COSV54008908; called by muse, mutect2, varscan2
- NOS3 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 56/332 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as COSV52495675; called by muse, mutect2, varscan2
- NPAS2 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 184/492 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV59562095; called by muse, varscan2
- NRSN1 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 52/284 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs769474942, COSV65894204; called by muse, mutect2, varscan2
- OBSL1 | c.1522C>T p.L508F | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV54729722; called by muse, mutect2, varscan2
- ODF1 | c.412C>G p.Q138E | Missense Mutation (SNP) | VAF 153/220 reads (70%) | SIFT tolerated (1); PolyPhen possibly damaging (0.848); catalogued as COSV53434202; called by muse, mutect2, varscan2
- ODF1 | c.599C>G p.S200C | Missense Mutation (SNP) | VAF 51/80 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as COSV53434215; called by muse, mutect2, varscan2
- OR10X1 | c.345A>T p.L115F | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as COSV63768005; called by muse, mutect2, varscan2
- OR1C1 | c.891G>A p.M297I | Missense Mutation (SNP) | VAF 71/126 reads (56%) | SIFT tolerated (0.26); PolyPhen benign (0.109); catalogued as COSV68715959; called by muse, mutect2, varscan2
- OR4F15 | c.258C>G p.F86L | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.076); catalogued as COSV59970369; called by muse, mutect2, varscan2
- PABPC3 | c.1418C>T p.T473M | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as rs190621317, COSV55805394; called by muse, varscan2
- PAPOLB | c.1591G>C p.E531Q | Missense Mutation (SNP) | VAF 63/111 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.184); catalogued as COSV68203546; called by muse, mutect2, varscan2
- PARD3 | c.349C>T p.Q117* | Nonsense Mutation (SNP) | VAF 56/155 reads (36%) | catalogued as rs1234358017, COSV60749222; called by muse, mutect2, varscan2
- PARD6B | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 50/76 reads (66%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.678); catalogued as COSV65405269; called by muse, mutect2, varscan2
- PCDHA2 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as rs1562156062, COSV65371111; called by muse, mutect2, varscan2
- PCDHB10 | c.2117C>T p.S706L | Missense Mutation (SNP) | VAF 94/176 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99505055; called by muse, mutect2, varscan2
- PCDHGB5 | c.1904G>A p.R635H | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs373709904, COSV54010066; called by muse, mutect2, varscan2
- PDE3A | c.2853C>G p.I951M | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV62982705; called by muse, mutect2, varscan2
- PER1 | c.3319G>A p.E1107K | Missense Mutation (SNP) | VAF 33/34 reads (97%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.542); catalogued as COSV57922078; called by muse, mutect2, varscan2
- PER3 | c.3592G>C p.E1198Q | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.638); catalogued as COSV62707877; called by muse, mutect2, varscan2
- PFKP | c.1225-1G>A p.X409_splice | Splice Site (SNP) | VAF 7/49 reads (14%) | catalogued as COSV66901574; called by muse, mutect2, varscan2
- PHF1 | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 33/41 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs762993282, COSV65703392; called by muse, mutect2, varscan2
- PIEZO2 | c.7893G>T p.W2631C | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53294178; called by muse, mutect2
- PILRA | c.707G>T p.R236M | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV52202524; called by muse, mutect2, varscan2
- PLA2G7 | c.443T>C p.V148A | Missense Mutation (SNP) | VAF 68/653 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as rs201022799, COSV51265748; called by muse, mutect2, varscan2
- PLOD1 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 71/118 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.197); catalogued as COSV52150425; called by muse, mutect2, varscan2
- PLXNB3 | c.5561C>G p.S1854C | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs939639089; called by muse, mutect2, varscan2
- PNLIPRP1 | c.1327G>C p.E443Q | Missense Mutation (SNP) | VAF 48/101 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.056); catalogued as COSV62613457; called by muse, mutect2, varscan2
- POLN | c.1399G>C p.E467Q | Missense Mutation (SNP) | VAF 41/62 reads (66%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as COSV67025350, COSV67027637; called by muse, mutect2, varscan2
- PPP2CA | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 42/56 reads (75%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV51538467; called by muse, mutect2, varscan2
- PPP2R3A | c.3001T>C p.Y1001H | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV53870684; called by muse, mutect2, varscan2
- PRMT7 | c.1684G>C p.E562Q | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV54716026; called by muse, mutect2, varscan2
- PRRC2A | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.259); catalogued as COSV63225030; called by muse, mutect2, varscan2
- PURA | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58762963; called by muse, mutect2, varscan2
- PWWP3A | c.606G>C p.E202D (on ENST00000627377; = p.E201D on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs372425730, COSV60905076; called by muse, mutect2, varscan2
- RALGPS1 | c.66C>A p.S22R | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52232593; called by muse, mutect2, varscan2
- RALGPS1 | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.056); catalogued as rs201112886, COSV52217859; called by muse, mutect2, varscan2
- RANBP6 | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 38/430 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1020977389, COSV52391559; called by muse, mutect2
- RARG | c.858G>C p.M286I | Missense Mutation (SNP) | VAF 116/202 reads (57%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as COSV58434696; called by muse, mutect2, varscan2
- RARG | c.700G>C p.A234P | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.918); catalogued as COSV58434727; called by muse, mutect2, varscan2
- RARS2 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 57/87 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs201899366, COSV57638114, COSV57641021; called by muse, mutect2, varscan2
- RASD2 | c.359A>G p.K120R | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV53353603; called by muse, mutect2, varscan2
- RCVRN | c.152G>A p.S51N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV56842520; called by muse, varscan2
- REV1 | c.1241G>C p.R414T | Missense Mutation (SNP) | VAF 47/190 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as COSV51490453; called by muse, mutect2, varscan2
- RIC1 | c.3736G>A p.E1246K | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.836); catalogued as COSV52615469; called by muse, mutect2
- RNF40 | c.563C>G p.S188C | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV61216697; called by muse, mutect2, varscan2
- RNF6 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 46/194 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); catalogued as COSV60420501; called by muse, mutect2, varscan2
- ROCK1 | c.586C>T p.H196Y | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67699339; called by muse, mutect2
- RP1 | c.1069G>A p.G357S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as rs758807313; called by muse, mutect2
- RP1 | c.3613C>T p.P1205S | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.236); catalogued as COSV55119147; called by muse, mutect2, varscan2
- RPAP1 | c.2245G>A p.E749K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.381); catalogued as COSV58542489; called by muse, mutect2, varscan2
- RPL3 | c.429G>C p.K143N | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV53366643; called by muse, mutect2, varscan2
- RTN4R | c.305C>G p.T102S | Missense Mutation (SNP) | VAF 59/88 reads (67%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV50383421; called by muse, mutect2, varscan2
- RYR1 | c.12676G>A p.E4226K | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1312489790, COSV62096875, COSV62110603; called by muse, mutect2, varscan2
- RYR3 | c.12014C>A p.P4005Q (on ENST00000389232; = p.P4006Q on NM_001036.6) | Missense Mutation (SNP) | VAF 91/224 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66799928; called by muse, mutect2, varscan2
- SCN5A | c.2994G>C p.Q998H | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV61138880, COSV61140764; called by muse, mutect2, varscan2
- SCYL3 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 128/174 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1288846983, COSV63044778, COSV99057107; called by muse, mutect2, varscan2
- SDC1 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 58/194 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54341612; called by muse, mutect2, varscan2
- SEC23B | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 89/168 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.215); catalogued as COSV52723896; called by muse, mutect2, varscan2
- SF3A3 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.971); catalogued as COSV65956873; called by muse, mutect2, varscan2
- SI | c.3866G>A p.G1289E | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52300864; called by muse, mutect2, varscan2
- SIAE | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV55013468; called by muse, mutect2, varscan2
- SLC16A2 | c.1170G>T p.Q390H | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.261); catalogued as COSV52088817; called by muse, mutect2, varscan2
- SLC30A10 | c.1161G>T p.L387F | Missense Mutation (SNP) | VAF 27/180 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as COSV63075648; called by muse, mutect2, varscan2
- SLC35A1 | c.301C>G p.Q101E | Missense Mutation (SNP) | VAF 37/66 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65780742; called by muse, mutect2, varscan2
- SLC52A1 | c.613G>C p.V205L | Missense Mutation (SNP) | VAF 37/267 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.053); catalogued as COSV54693838; called by muse, mutect2, varscan2
- SLC5A4 | c.1765G>A p.E589K | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as rs761787598, COSV56673912, COSV99832104; called by muse, mutect2, varscan2
- SLC7A6 | c.935C>T p.T312M | Missense Mutation (SNP) | VAF 81/177 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.327); catalogued as rs922598962, COSV54719358; called by muse, mutect2, varscan2
- SLCO2A1 | c.794C>T p.S265L | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV60489424; called by muse, mutect2, varscan2
- SMARCC2 | c.1183G>C p.E395Q | Missense Mutation (SNP) | VAF 91/145 reads (63%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); catalogued as COSV57224938, COSV57225147; called by muse, mutect2, varscan2
- SMURF2 | c.2014C>G p.L672V | Missense Mutation (SNP) | VAF 118/241 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.442); catalogued as COSV52319808; called by muse, mutect2, varscan2
- SNAP29 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV53144232; called by muse, mutect2, varscan2
- SNX19 | c.133C>G p.L45V | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs772159960, COSV56288692; called by muse, mutect2, varscan2
- SOCS5 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs773033292, COSV60605617, COSV60606423; called by muse, mutect2, varscan2
- SON | c.4784C>T p.S1595F | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.102); catalogued as COSV51670701; called by muse, mutect2, varscan2
- SPAG17 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.96); catalogued as COSV60468426; called by muse, mutect2, varscan2
- SPTBN1 | c.3363G>A p.M1121I | Missense Mutation (SNP) | VAF 91/247 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as COSV61694031; called by muse, mutect2, varscan2
- SPTLC1 | c.325C>T p.L109F | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV52767004; called by muse, mutect2, varscan2
- ST18 | c.1864C>G p.R622G | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV52485545, COSV52501022, COSV52509349; called by muse, mutect2, varscan2
- ST3GAL6 | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.059); catalogued as COSV54578862, COSV54580355, COSV54585003; called by muse, mutect2, varscan2
- ST8SIA1 | c.411A>T p.K137N | Missense Mutation (SNP) | VAF 141/275 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV53959154; called by muse, mutect2, varscan2
- STAB2 | c.5126A>C p.D1709A | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV66347070; called by muse, mutect2, varscan2
- STX3 | c.536C>T p.S179F | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as COSV55701268; called by muse, mutect2, varscan2
- SUPT6H | c.2385C>G p.F795L | Missense Mutation (SNP) | VAF 119/173 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV58931431; called by muse, mutect2, varscan2
- SYNE1 | c.3796G>A p.E1266K (on ENST00000367255 / NM_182961.4; = p.E1273K on NM_033071.3) | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV55100686; called by muse, mutect2, varscan2
- SYNE1 | c.3573G>C p.L1191F (on ENST00000367255 / NM_182961.4; = p.L1198F on NM_033071.3) | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV55100729, COSV99565255; called by muse, mutect2, varscan2
- SYNE2 | c.11124G>C p.Q3708H | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as COSV59970192; called by muse, mutect2, varscan2
- SYNE2 | c.19122G>C p.Q6374H | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.497); catalogued as COSV59965913, COSV59970208; called by muse, mutect2, varscan2
- TAX1BP1 | c.808G>C p.E270Q | Missense Mutation (SNP) | VAF 60/137 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as rs371052683; called by muse, mutect2, varscan2
- TBL1XR1 | c.1087C>G p.L363V | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV70504160; called by muse, mutect2, varscan2
- TBRG4 | c.1178T>G p.V393G | Missense Mutation (SNP) | VAF 26/229 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV51834481; called by muse, mutect2, varscan2
- TCAP | c.476C>T p.S159F | Missense Mutation (SNP) | VAF 158/351 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV54094107; called by muse, mutect2, varscan2
- TCF20 | c.3737C>G p.S1246C | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV59495912; called by muse, mutect2, varscan2
- TEK | c.2166C>G p.N722K | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.98); PolyPhen benign (0.007); catalogued as COSV66234579; called by muse, mutect2, varscan2
- TENM2 | c.4021G>A p.E1341K (on ENST00000518659 / NM_001122679.2; = p.E1102K on NM_001080428.3) | Missense Mutation (SNP) | VAF 126/156 reads (81%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV69141201; called by muse, mutect2, varscan2
- TET3 | c.3484C>T p.R1162W | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV69645627; called by muse, mutect2, varscan2
- TFR2 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.886); catalogued as COSV56156496; called by muse, mutect2, varscan2
- TFRC | c.1936C>T p.R646C | Missense Mutation (SNP) | VAF 77/149 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV64054484, COSV64056511; called by muse, mutect2, varscan2
- THOC6 | c.363G>C p.R121S | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV50188239; called by muse, mutect2, varscan2
- TIMM44 | c.1239G>A p.P413= | Splice Region (SNP) | VAF 129/233 reads (55%) | catalogued as COSV54494609, COSV99564018; called by muse, mutect2, varscan2
- TM4SF4 | c.595G>C p.D199H | Missense Mutation (SNP) | VAF 84/137 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.127); catalogued as COSV59515330; called by muse, mutect2, varscan2
- TMEM132A | c.1834G>A p.E612K (on ENST00000453848 / NM_178031.3; = p.E613K on NM_017870.4) | Missense Mutation (SNP) | VAF 41/64 reads (64%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.693); catalogued as COSV50022952; called by muse, mutect2, varscan2
- TMEM38B | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.5); catalogued as COSV65951417; called by muse, mutect2, varscan2
- TMEM40 | c.330G>C p.L110F | Missense Mutation (SNP) | VAF 89/212 reads (42%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.568); catalogued as COSV53148694; called by muse, mutect2, varscan2
- TMEM71 | c.16C>G p.Q6E | Missense Mutation (SNP) | VAF 61/396 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.291); catalogued as COSV63458059; called by muse, mutect2, varscan2
- TNN | c.2498C>G p.S833C | Missense Mutation (SNP) | VAF 151/199 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53435475; called by muse, mutect2, varscan2
- TPP2 | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as COSV65754941; called by muse, mutect2, varscan2
- TRRAP | c.2866G>A p.E956K | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.134); catalogued as COSV62854383; called by muse, mutect2, varscan2
- TSKU | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.145); catalogued as rs1214268385, COSV60752861; called by muse, mutect2, varscan2
- TTC16 | c.1676C>T p.P559L | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV60161231; called by muse, mutect2, varscan2
- TULP2 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 76/235 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as COSV55480205; called by muse, mutect2, varscan2
- TXN2 | c.61C>G p.Q21E | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.051); catalogued as COSV53398372; called by muse, mutect2, varscan2
- UBE2O | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 59/155 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.355); catalogued as COSV60066844; called by muse, mutect2, varscan2
- UBE3A | c.1375G>C p.E459Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.893); catalogued as COSV51665759; called by muse, mutect2
- UBR4 | c.3617C>G p.S1206C | Missense Mutation (SNP) | VAF 88/132 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs555728639, COSV64382807; called by muse, mutect2, varscan2
- USH2A | c.1804G>C p.G602R | Missense Mutation (SNP) | VAF 44/257 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100243877, COSV56435715; called by muse, mutect2, varscan2
- USP21 | c.366G>A p.M122I | Missense Mutation (SNP) | VAF 28/287 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV57091236; called by muse, mutect2, varscan2
- USP28 | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.506); catalogued as rs772411866, COSV50163674; called by muse, mutect2, varscan2
- USP29 | c.2734G>A p.E912K | Missense Mutation (SNP) | VAF 93/203 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV54143461; called by muse, mutect2, varscan2
- USP8 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs772324296, COSV56168497; called by muse, mutect2, varscan2
- VPS13C | c.7138C>T p.H2380Y (on ENST00000644861 / NM_020821.3; = p.H2337Y on NM_017684.5) | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV51424474; called by muse, varscan2
- VPS26B | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV55546595; called by muse, mutect2, varscan2
- WDFY3 | c.1669C>T p.L557F | Missense Mutation (SNP) | VAF 44/227 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV55713720; called by muse, mutect2, varscan2
- WDR55 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs557759167, COSV56906817; called by muse, mutect2, varscan2
- ZBTB24 | c.726G>C p.K242N | Missense Mutation (SNP) | VAF 58/176 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.462); catalogued as COSV57783371; called by muse, mutect2, varscan2
- ZDHHC20 | c.983G>A p.S328N (on ENST00000400590 / NM_001330059.2; = p.S327N on NM_153251.3) | Missense Mutation (SNP) | VAF 42/59 reads (71%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.787); catalogued as COSV57188590; called by muse, mutect2, varscan2
- ZFP37 | c.1253C>T p.S418L | Missense Mutation (SNP) | VAF 60/101 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV65285721; called by muse, mutect2, varscan2
- ZFP37 | c.859C>T p.Q287* | Nonsense Mutation (SNP) | VAF 68/123 reads (55%) | catalogued as rs780691441; called by muse, mutect2, varscan2
- ZMYND8 | c.1929G>C p.E643D (on ENST00000311275 / NM_001363741.2; = p.E663D on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/231 reads (21%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.005); catalogued as COSV53696208; called by muse, mutect2, varscan2
- ZNF148 | c.1257G>T p.E419D | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV62307650; called by muse, mutect2, varscan2
- ZNF207 | c.83A>G p.Q28R | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV58302142; called by muse, mutect2, varscan2
- ZNF223 | c.1284C>G p.F428L | Missense Mutation (SNP) | VAF 68/146 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV71572193; called by muse, mutect2, varscan2
- ZNF230 | c.466G>C p.D156H | Missense Mutation (SNP) | VAF 87/221 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV71273712; called by muse, mutect2, varscan2
- ZNF281 | c.2558C>G p.S853C | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV54169864; called by muse, mutect2, varscan2
- ZNF442 | c.50C>G p.S17C | Missense Mutation (SNP) | VAF 9/188 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.7); catalogued as COSV54423315; called by muse, mutect2
- ZNF480 | c.394T>A p.F132I | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.095); catalogued as COSV57998356; called by muse, mutect2, varscan2
- ZNF493 | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 17/20 reads (85%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV62749117, COSV62752275; called by muse, mutect2, varscan2
- ZNF493 | c.1399C>T p.H467Y | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); catalogued as COSV62752283; called by muse, mutect2, varscan2
- ZNF493 | c.1877C>T p.S626L | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV62752292; called by muse, varscan2
- ZNF493 | c.1915C>T p.H639Y | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as COSV62750374, COSV62752300; called by muse, varscan2
- ZNF544 | c.826G>A p.G276R | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.316); catalogued as COSV54138440; called by muse, mutect2, varscan2
- ZNF544 | c.827G>T p.G276V | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.733); catalogued as COSV54138449; called by muse, mutect2, varscan2
- ZNF585B | c.2225G>C p.G742A | Missense Mutation (SNP) | VAF 13/272 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.377); catalogued as COSV57217019; called by muse, mutect2
- ZNF687 | c.28G>C p.D10H | Missense Mutation (SNP) | VAF 273/446 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1276672607, COSV60682330; called by muse, mutect2, varscan2
- ZNF761 | c.1723G>C p.E575Q | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.167); catalogued as COSV61889487; called by muse, mutect2, varscan2
- ZNF831 | c.2632G>A p.E878K | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0.078); catalogued as COSV64038846; called by muse, mutect2, varscan2
- ZNF91 | c.787G>C p.E263Q | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as COSV56088306; called by muse, mutect2
- ACAP2 | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2
- ANKRD11 | c.3297_3299delinsTT p.S1100Lfs*218 | Frame Shift Del (DEL) | VAF 13/66 reads (20%) | called by pindel, varscan2*
- ARHGAP32 | c.553C>G p.L185V | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- ARID4B | c.1564G>T p.E522* | Nonsense Mutation (SNP) | VAF 24/96 reads (25%) | called by muse, mutect2, varscan2
- ASCC2 | c.2191G>T p.E731* | Nonsense Mutation (SNP) | VAF 140/615 reads (23%) | called by muse, mutect2, varscan2
- ATP6V1C1 | c.391C>G p.Q131E | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); called by muse, mutect2
- CBLB | c.1868C>G p.S623* | Nonsense Mutation (SNP) | VAF 22/81 reads (27%) | called by muse, mutect2, varscan2
- CCDC88A | c.5275C>T p.R1759* (on ENST00000436346 / NM_001365480.1; = p.R1731* on NM_018084.5) | Nonsense Mutation (SNP) | VAF 43/100 reads (43%) | called by muse, mutect2, varscan2
- CNOT11 | c.1255G>C p.D419H | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- COG8 | c.971C>G p.S324* | Nonsense Mutation (SNP) | VAF 28/90 reads (31%) | called by muse, mutect2, varscan2
- COL6A6 | c.3107G>A p.R1036K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2
- CRB1 | c.2770G>T p.E924* | Nonsense Mutation (SNP) | VAF 32/100 reads (32%) | called by muse, mutect2, varscan2
- DNAH3 | c.1771C>G p.Q591E | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.001); called by muse, mutect2
- EDRF1 | c.589G>C p.E197Q | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- EXOSC10 | c.2209G>T p.E737* (on ENST00000376936 / NM_001001998.3; = p.E712* on NM_002685.4) | Nonsense Mutation (SNP) | VAF 44/132 reads (33%) | called by muse, mutect2, varscan2
- FBXL22 | c.653G>A p.R218K | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- GGNBP2 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- GIPR | c.627G>A p.W209* | Nonsense Mutation (SNP) | VAF 25/95 reads (26%) | called by muse, mutect2, varscan2
- GRIP2 | c.160C>A p.H54N | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- IQUB | c.2330C>G p.S777* | Nonsense Mutation (SNP) | VAF 20/42 reads (48%) | called by muse, mutect2, varscan2
- LCA5 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LIPG | c.697C>T p.Q233* | Nonsense Mutation (SNP) | VAF 42/100 reads (42%) | called by muse, mutect2, varscan2
- LTN1 | c.1681G>C p.E561Q | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.18); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MAP1B | c.5617C>T p.Q1873* | Nonsense Mutation (SNP) | VAF 32/39 reads (82%) | called by muse, mutect2, varscan2
- MAP3K5 | c.3875-1G>A p.X1292_splice | Splice Site (SNP) | VAF 9/27 reads (33%) | called by muse, mutect2
- MLLT6 | c.1969C>T p.R657W | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MRC1 | c.3145G>T p.D1049Y | Missense Mutation (SNP) | VAF 24/204 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- OR52I1 | c.971C>G p.S324* | Nonsense Mutation (SNP) | VAF 29/131 reads (22%) | called by muse, mutect2, varscan2
- PAK6 | c.1816_1827del p.P606_A609del | In Frame Del (DEL) | VAF 71/140 reads (51%) | called by mutect2, pindel, varscan2
- PCNX4 | c.1647G>C p.L549F (on ENST00000406854 / NM_001330177.2; = p.L315F on NM_022495.5) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- PHF3 | c.3473C>T p.A1158V | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- PIK3C2A | c.1300C>T p.Q434* | Nonsense Mutation (SNP) | VAF 29/155 reads (19%) | called by muse, mutect2, varscan2
- RAP1GDS1 | c.709G>C p.E237Q (on ENST00000408927 / NM_001100427.2; = p.E238Q on NM_021159.5) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.241); called by muse, mutect2
- SEMA4B | c.573C>G p.F191L | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- SHC2 | c.1680G>C p.Q560H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- STYXL2 | c.2286C>A p.C762* | Nonsense Mutation (SNP) | VAF 112/151 reads (74%) | called by muse, mutect2, varscan2
- SYNE1 | c.5740C>T p.Q1914* (on ENST00000367255 / NM_182961.4; = p.Q1921* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | called by muse, varscan2
- TAS1R3 | c.1225C>T p.Q409* | Nonsense Mutation (SNP) | VAF 18/82 reads (22%) | called by muse, mutect2, varscan2
- VPS13C | c.3499G>T p.E1167* (on ENST00000644861 / NM_020821.3; = p.E1124* on NM_017684.5) | Nonsense Mutation (SNP) | VAF 138/246 reads (56%) | called by muse, mutect2, varscan2
- WAC | c.947C>G p.S316* | Nonsense Mutation (SNP) | VAF 84/210 reads (40%) | called by muse, mutect2, varscan2
- YY1AP1 | c.1454C>A p.S485* (on ENST00000295566 / NM_139118.2; = p.S428* on NM_018253.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 133/215 reads (62%) | called by muse, mutect2, varscan2
- ACTR8 | c.1443G>T p.L481= | Silent (SNP) | VAF 104/199 reads (52%) | catalogued as rs201085829; called by muse, mutect2, varscan2
- ADAM22 | c.729G>C p.L243= | Silent (SNP) | VAF 39/104 reads (38%) | catalogued as COSV55990179; called by muse, mutect2, varscan2
- ADCK1 | c.1290C>G p.L430= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as COSV53085880; called by muse, mutect2, varscan2
- ADGRL3 | c.3054C>T p.F1018= (on ENST00000506720 / NM_001322402.2; = p.F950= on NM_015236.6) | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV72231944; called by muse, mutect2, varscan2
- AHNAK | c.8148G>A p.L2716= | Silent (SNP) | VAF 70/285 reads (25%) | catalogued as COSV57217522; called by muse, mutect2, varscan2
- AHNAK2 | c.2301G>A p.K767= | Silent (SNP) | VAF 53/81 reads (65%) | catalogued as rs747383496, COSV60930557; called by muse, mutect2, varscan2
- AKT1 | c.324C>T p.D108= | Silent (SNP) | VAF 27/38 reads (71%) | catalogued as rs940028787, COSV62574152, COSV62575976; ClinVar: likely benign; called by muse, mutect2, varscan2
- ANKRD11 | c.846C>T p.L282= | Silent (SNP) | VAF 82/174 reads (47%) | catalogued as rs1440336123, COSV56371860; called by muse, mutect2, varscan2
- AOX1 | c.747G>T p.L249= | Silent (SNP) | VAF 103/151 reads (68%) | catalogued as COSV65983953; called by muse, mutect2, varscan2
- AP1B1 | c.1467G>A p.V489= | Silent (SNP) | VAF 70/92 reads (76%) | catalogued as COSV58023422; called by muse, mutect2, varscan2
- BMP6 | c.415C>T p.L139= | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as rs781542945, COSV51672362; called by muse, mutect2, varscan2
- BMP6 | c.562C>T p.L188= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs764460136, COSV51672374; called by muse, mutect2, varscan2
- CADM3 | c.156G>A p.V52= (on ENST00000368125 / NM_001127173.3; = p.V86= on NM_021189.5) | Silent (SNP) | VAF 98/160 reads (61%) | catalogued as COSV63687394; called by muse, varscan2
- CADM3 | c.225G>A p.K75= (on ENST00000368125 / NM_001127173.3; = p.K109= on NM_021189.5) | Silent (SNP) | VAF 62/103 reads (60%) | catalogued as COSV63687397; called by muse, varscan2
- CASKIN1 | c.747G>T p.V249= | Silent (SNP) | VAF 30/120 reads (25%) | catalogued as COSV58876883; called by muse, mutect2, varscan2
- CASP14 | c.336G>T p.L112= | Silent (SNP) | VAF 33/90 reads (37%) | catalogued as COSV55666638; called by muse, mutect2, varscan2
- CFAP53 | c.678G>C p.L226= | Silent (SNP) | VAF 39/112 reads (35%) | catalogued as COSV68352894; called by muse, mutect2, varscan2
- CHRNA6 | c.1062G>A p.L354= | Silent (SNP) | VAF 57/99 reads (58%) | catalogued as COSV52381037; called by muse, mutect2, varscan2
- CHST7 | c.792G>A p.L264= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as rs780932142; called by muse, mutect2
- CIC | c.2943G>C p.L981= | Silent (SNP) | VAF 88/158 reads (56%) | catalogued as COSV50664636; called by muse, mutect2, varscan2
- CLK2 | c.1059C>T p.I353= (on ENST00000368361 / NM_001294339.2; = p.I352= on NM_003993.4) | Silent (SNP) | VAF 45/246 reads (18%) | catalogued as COSV56947409; called by muse, mutect2, varscan2
- COG8 | c.6G>A p.A2= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as rs142062440; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL18A1 | c.615C>G p.L205= | Silent (SNP) | VAF 21/84 reads (25%) | catalogued as COSV62707224; called by muse, mutect2, varscan2
- DAB2IP | c.2901G>A p.L967= (on ENST00000408936; = p.L939= on NM_032552.3) | Silent (SNP) | VAF 20/30 reads (67%) | catalogued as rs913142001, COSV52267929; called by muse, mutect2, varscan2
- DDX43 | c.1266G>A p.Q422= | Silent (SNP) | VAF 57/222 reads (26%) | catalogued as COSV64813796; called by muse, mutect2, varscan2
- DENND2C | c.1596G>A p.E532= (on ENST00000393274 / NM_001256404.2; = p.E475= on NM_198459.4) | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV67924040; called by muse, varscan2
- DNAH11 | c.10042C>T p.L3348= | Silent (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- DYSF | c.303C>T p.F101= | Silent (SNP) | VAF 265/300 reads (88%) | catalogued as COSV50581621; called by muse, mutect2, varscan2
- EBNA1BP2 | c.180C>T p.F60= | Silent (SNP) | VAF 185/323 reads (57%) | catalogued as COSV52540768, COSV52541639; called by muse, mutect2, varscan2
- EFHB | c.423G>T p.G141= | Silent (SNP) | VAF 24/108 reads (22%) | catalogued as COSV55553661; called by muse, mutect2, varscan2
- EIF2AK2 | c.417G>A p.Q139= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV51799300; called by muse, mutect2, varscan2
- ERN2 | c.6G>A p.A2= | Silent (SNP) | VAF 8/13 reads (62%) | called by mutect2, varscan2
- ESRRG | c.189C>T p.D63= | Silent (SNP) | VAF 43/131 reads (33%) | catalogued as rs376743939; called by muse, mutect2, varscan2
- FAAP20 | c.327G>A p.G109= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV66032594; called by muse, mutect2, varscan2
- FOXN2 | c.33G>A p.K11= | Silent (SNP) | VAF 89/105 reads (85%) | catalogued as rs1025746762, COSV61319868; called by muse, mutect2, varscan2
- GABPB2 | c.291G>T p.V97= | Silent (SNP) | VAF 112/318 reads (35%) | catalogued as COSV64461587; called by muse, mutect2, varscan2
- GALNT2 | c.1593G>C p.L531= | Silent (SNP) | VAF 21/92 reads (23%) | catalogued as COSV64192596; called by muse, mutect2, varscan2
- GNE | c.321G>C p.V107= (on ENST00000396594 / NM_001128227.3; = p.V76= on NM_005476.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/248 reads (12%) | catalogued as COSV64953099; called by muse, mutect2, varscan2
- GPI | c.1056C>T p.F352= | Silent (SNP) | VAF 48/108 reads (44%) | catalogued as rs779401223, COSV62894916; called by muse, mutect2, varscan2
- H2BC6 | c.222C>T p.I74= | Silent (SNP) | VAF 337/370 reads (91%) | catalogued as rs769608700, COSV61590933; called by muse, mutect2, varscan2
- HIP1R | c.603C>T p.I201= | Silent (SNP) | VAF 103/405 reads (25%) | catalogued as rs762232461, COSV53441018; called by muse, mutect2, varscan2
- HRNR | c.2295C>T p.H765= | Silent (SNP) | VAF 34/223 reads (15%) | catalogued as rs773868367, COSV64262895; called by muse, varscan2
- IMPG2 | c.250C>T p.L84= | Silent (SNP) | VAF 29/128 reads (23%) | catalogued as COSV51985643; called by muse, mutect2, varscan2
- KHDC4 | c.1230G>A p.P410= | Silent (SNP) | VAF 27/150 reads (18%) | catalogued as rs766194829, COSV64165718; called by muse, mutect2, varscan2
- KLF13 | c.441C>G p.L147= | Silent (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- KMT2D | c.828C>T p.C276= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs1179683526, COSV56486108; called by muse, mutect2, varscan2
- LRP11 | c.720C>T p.I240= | Silent (SNP) | VAF 45/83 reads (54%) | catalogued as rs187562016, COSV53335468; called by muse, mutect2, varscan2
- LRRIQ4 | c.135C>T p.F45= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as COSV61620218; called by muse, mutect2, varscan2
- LRSAM1 | c.2171G>A p.*724= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV55943221; called by muse, mutect2, varscan2
- MAN2B1 | c.1593C>T p.S531= | Silent (SNP) | VAF 127/210 reads (60%) | catalogued as rs757131800, COSV55475275; called by muse, mutect2, varscan2
- MMRN1 | c.2436T>C p.D812= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV53342687; called by muse, mutect2, varscan2
- MR1 | c.426G>C p.L142= | Silent (SNP) | VAF 43/95 reads (45%) | catalogued as COSV51582208; called by muse, mutect2, varscan2
- N4BP2 | c.1023G>A p.V341= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as COSV54706907; called by muse, mutect2, varscan2
- NCOA6 | c.258G>A p.Q86= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as COSV62868003; called by muse, mutect2, varscan2
- NEB | c.10971G>C p.L3657= | Silent (SNP) | VAF 56/63 reads (89%) | catalogued as COSV51459788; called by muse, mutect2, varscan2
- NID2 | c.3666C>T p.V1222= | Silent (SNP) | VAF 37/101 reads (37%) | catalogued as COSV53502849; called by muse, mutect2, varscan2
- NOBOX | c.921G>A p.Q307= | Silent (SNP) | VAF 36/111 reads (32%) | catalogued as COSV56197781; called by muse, mutect2, varscan2
- NOL6 | c.2043G>A p.L681= | Silent (SNP) | VAF 110/198 reads (56%) | catalogued as COSV53040502; called by muse, mutect2, varscan2
- NPTX1 | c.603C>A p.I201= | Silent (SNP) | VAF 37/99 reads (37%) | catalogued as COSV60774675, COSV60776473; called by muse, mutect2, varscan2
- NT5C3A | c.201C>T p.I67= (on ENST00000610140 / NM_001374335.1; = p.I33= on NM_016489.13) | Silent (SNP) | VAF 16/97 reads (16%) | called by muse, mutect2
- OR4A5 | c.66A>G p.Q22= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV60524676; called by muse, mutect2
- OR4D11 | c.309C>T p.L103= | Silent (SNP) | VAF 119/186 reads (64%) | catalogued as rs1202594924, COSV57585609; called by muse, mutect2, varscan2
- OTOP1 | c.1179C>T p.L393= | Silent (SNP) | VAF 61/130 reads (47%) | catalogued as COSV56396771; called by muse, mutect2, varscan2
- PAQR9 | c.162C>T p.F54= | Silent (SNP) | VAF 8/13 reads (62%) | called by muse, mutect2, varscan2
- PAXX | c.198G>C p.L66= | Silent (SNP) | VAF 37/195 reads (19%) | catalogued as COSV65406822; called by muse, mutect2, varscan2
- PCDH15 | c.4734C>T p.R1578= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV64737115; called by muse, mutect2, varscan2
- PER1 | c.2334G>C p.L778= | Silent (SNP) | VAF 21/22 reads (95%) | catalogued as COSV57922085; called by muse, mutect2, varscan2
- POU6F1 | c.1305C>T p.V435= | Silent (SNP) | VAF 61/269 reads (23%) | catalogued as COSV61327748; called by muse, varscan2
- POU6F1 | c.1227C>T p.V409= | Silent (SNP) | VAF 59/225 reads (26%) | catalogued as COSV61327764; called by muse, varscan2
- PROZ | c.103C>T p.L35= | Silent (SNP) | VAF 85/370 reads (23%) | catalogued as COSV61440476; called by muse, mutect2, varscan2
- PSME1 | c.360G>A p.E120= | Silent (SNP) | VAF 38/98 reads (39%) | catalogued as COSV52825875; called by muse, mutect2, varscan2
- RAB40C | c.675C>T p.F225= | Silent (SNP) | VAF 69/280 reads (25%) | catalogued as COSV50195563; called by muse, mutect2, varscan2
- RANBP17 | c.420C>G p.L140= | Silent (SNP) | VAF 30/113 reads (27%) | catalogued as rs764952588, COSV66657037; called by muse, mutect2, varscan2
- RANBP17 | c.1890G>A p.V630= | Silent (SNP) | VAF 20/21 reads (95%) | catalogued as COSV66657041; called by muse, varscan2
- RBM28 | c.456G>A p.K152= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV56164858; called by muse, mutect2, varscan2
- RBM48 | c.9G>A p.S3= | Silent (SNP) | VAF 34/77 reads (44%) | catalogued as COSV50419069; called by muse, mutect2, varscan2
- RHD | c.72C>T p.L24= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV59647237; called by muse, mutect2, varscan2
- RICTOR | c.4185G>A p.L1395= | Silent (SNP) | VAF 34/65 reads (52%) | catalogued as COSV57124600; called by muse, mutect2, varscan2
- RNF40 | c.666C>G p.L222= | Silent (SNP) | VAF 20/117 reads (17%) | catalogued as COSV61216703; called by muse, mutect2, varscan2
- RRNAD1 | c.12C>T p.I4= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV57461317; called by muse, mutect2, varscan2
- SARDH | c.2577C>T p.F859= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as rs778890723; called by muse, mutect2
- SDK2 | c.3486C>T p.I1162= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as rs779642580, COSV66196750; called by muse, mutect2, varscan2
- SEMA3E | c.1965G>A p.Q655= | Silent (SNP) | VAF 43/113 reads (38%) | catalogued as COSV57108657; called by muse, mutect2, varscan2
- SIPA1L3 | c.3402C>T p.V1134= | Silent (SNP) | VAF 400/772 reads (52%) | catalogued as COSV55924206; called by muse, mutect2, varscan2
- SLC15A2 | c.987G>A p.R329= | Silent (SNP) | VAF 20/97 reads (21%) | catalogued as COSV55200985; called by muse, mutect2, varscan2
- SLC18A2 | c.705C>A p.G235= | Silent (SNP) | VAF 40/123 reads (33%) | catalogued as COSV53693545; called by muse, mutect2, varscan2
- SLC1A4 | c.393C>T p.L131= | Silent (SNP) | VAF 25/28 reads (89%) | catalogued as COSV52235987; called by muse, mutect2, varscan2
- SLC5A3 | c.514C>T p.L172= | Silent (SNP) | VAF 36/135 reads (27%) | catalogued as COSV62973486; called by muse, mutect2, varscan2
- SMAD3 | c.888C>G p.L296= | Silent (SNP) | VAF 29/140 reads (21%) | catalogued as COSV59290052, COSV59290523; called by muse, mutect2, varscan2
- SMG5 | c.2268C>G p.L756= | Silent (SNP) | VAF 63/262 reads (24%) | catalogued as COSV62437697; called by muse, mutect2, varscan2
- SOCS6 | c.348G>A p.V116= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as COSV67547127; called by muse, mutect2, varscan2
- SPEM2 | c.879C>T p.V293= | Silent (SNP) | VAF 21/148 reads (14%) | catalogued as COSV61604631; called by muse, mutect2, varscan2
- SS18 | c.1119T>A p.G373= (on ENST00000415083 / NM_001007559.3; = p.G342= on NM_005637.3) | Silent (SNP) | VAF 25/94 reads (27%) | catalogued as COSV52263915; called by muse, mutect2, varscan2
- ST18 | c.1035C>T p.I345= | Silent (SNP) | VAF 46/239 reads (19%) | catalogued as rs144551525; called by muse, mutect2, varscan2
- SYNPO2 | c.1599G>A p.T533= | Silent (SNP) | VAF 25/46 reads (54%) | catalogued as rs1321909445, COSV61116994; called by muse, mutect2, varscan2
- TACO1 | c.198C>T p.V66= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as COSV51976502; called by muse, mutect2, varscan2
- TBC1D1 | c.3447G>A p.R1149= | Silent (SNP) | VAF 21/274 reads (8%) | catalogued as rs771129905, COSV54727327; called by muse, mutect2
- TBCE | c.1257C>G p.L419= (on ENST00000366601; = p.L482= on NM_003193.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/179 reads (19%) | catalogued as COSV64004593; called by muse, mutect2, varscan2
- TGM1 | c.1380C>T p.A460= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as rs1358457732, COSV52865500; called by muse, mutect2, varscan2
- TMEM214 | c.1146G>A p.K382= | Silent (SNP) | VAF 26/144 reads (18%) | catalogued as COSV53194049; called by muse, mutect2, varscan2
- TMEM255B | c.504C>T p.C168= | Silent (SNP) | VAF 35/48 reads (73%) | catalogued as rs1295511930, COSV64704857; called by muse, mutect2, varscan2
- TOX2 | c.1251C>A p.P417= (on ENST00000358131 / NM_001098798.2; = p.P393= on NM_032883.3) | Silent (SNP) | VAF 54/84 reads (64%) | catalogued as COSV57895530; called by muse, mutect2, varscan2
- TRIM32 | c.1323G>A p.L441= | Silent (SNP) | VAF 75/334 reads (22%) | catalogued as COSV57817282; called by muse, mutect2, varscan2
- TRRAP | c.4182G>A p.L1394= | Silent (SNP) | VAF 55/294 reads (19%) | catalogued as COSV62854392; called by muse, mutect2, varscan2
- TSKU | c.102C>T p.F34= | Silent (SNP) | VAF 35/135 reads (26%) | catalogued as rs767229761, COSV60752849; called by muse, mutect2, varscan2
- TXNDC5 | c.720C>T p.V240= | Silent (SNP) | VAF 38/182 reads (21%) | catalogued as rs1280876721, COSV65731005; called by muse, varscan2
- UCHL5 | c.30C>T p.L10= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as COSV66477961; called by muse, mutect2, varscan2
- UQCC1 | c.813G>A p.G271= | Silent (SNP) | VAF 87/152 reads (57%) | catalogued as COSV62903626; called by muse, mutect2, varscan2
- USP40 | c.3630C>T p.I1210= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as rs373474102; called by muse, mutect2, varscan2
- XPO6 | c.1512G>A p.L504= | Silent (SNP) | VAF 84/142 reads (59%) | catalogued as rs529603592, COSV58971569; called by muse, varscan2
- ZAN | c.4398C>T p.F1466= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs1018055627, COSV61816382; called by muse, mutect2, varscan2
- ZNF521 | c.1137G>A p.K379= | Silent (SNP) | VAF 28/141 reads (20%) | catalogued as COSV64127074, COSV64127844; called by muse, mutect2, varscan2
- ZNF536 | c.417C>T p.F139= | Silent (SNP) | VAF 247/306 reads (81%) | catalogued as COSV62818509, COSV62823576; called by muse, mutect2, varscan2
- ZNF766 | c.24C>T p.H8= | Silent (SNP) | VAF 178/383 reads (46%) | catalogued as COSV63010247; called by muse, mutect2, varscan2
- C1orf229 | n.386G>A | RNA (SNP) | VAF 5/11 reads (45%) | called by muse, mutect2, varscan2
- COL18A1-AS1 | n.1539G>C | RNA (SNP) | VAF 18/78 reads (23%) | catalogued as COSV101181786; called by muse, mutect2, varscan2
- DST-AS1 | n.139+7517G>C | Intron (SNP) | VAF 8/24 reads (33%) | catalogued as COSV66107883; called by muse, mutect2, varscan2
- FOLH1B | n.1547C>A | RNA (SNP) | VAF 7/72 reads (10%) | called by muse, mutect2
- LIMK2 | c.1773-1215C>G | Intron (SNP) | VAF 26/119 reads (22%) | catalogued as COSV53224866; called by muse, mutect2, varscan2
- MGAM | c.4618+301C>T | Intron (SNP) | VAF 27/46 reads (59%) | catalogued as rs1199033944, COSV72075117; called by muse, mutect2, varscan2
- MORF4 | n.845G>C | RNA (SNP) | VAF 29/79 reads (37%) | called by muse, mutect2, varscan2
- NDUFV3 | c.170-5045G>C | Intron (SNP) | VAF 38/115 reads (33%) | catalogued as COSV61088593; called by muse, mutect2, varscan2
- OR3A4P | n.334G>T | RNA (SNP) | VAF 44/234 reads (19%) | called by muse, mutect2, varscan2
- RNASET2 | c.446+303C>G | Intron (SNP) | VAF 28/70 reads (40%) | called by muse, mutect2, varscan2
- RPL13 | c.246+99G>C | Intron (SNP) | VAF 14/37 reads (38%) | catalogued as rs777910066, COSV99244969; called by muse, mutect2, varscan2
- TMEM105 | n.794C>T | RNA (SNP) | VAF 156/289 reads (54%) | catalogued as rs200357228; called by muse, mutect2, varscan2
